Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A417, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A417-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of papillae having an fine fibrovascular stalk or folliculae covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle or begnin tissue. The cells tend to maintain their polarity. Nuclei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is necrotic, fibrous and invasion of skeletal muscle.

Path Report: Tumor type: Papillary carcinoma

ICD-O-3

Tumor size: 2.5x2x1.8cm

carcinoma, papillary, thyroid
8260/3

Laterality: right

Site: thyroid, NOS C73.9

Focality: unifocal

7-20-12
RD

Extracapsular extension: Not specified

Source: NCI Genomic Data Commons file 287b01d2-5dc5-4f13-ba0f-bfae013c5c74 (TCGA-E8-A417.F78F1D53-5654-494C-978D-C0575D52D46F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).